Somatic mutation profile of tumor specimen TCGA-GC-A3WC-01A (aliquot TCGA-GC-A3WC-01A-31D-A22Z-08) from TCGA case TCGA-GC-A3WC, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 80.2 years (29,295 days).
Specimen TCGA-GC-A3WC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6c9893f0-f99b-4d53-9629-5ddc958169c1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-GC-A3WC-10A (Blood Derived Normal), aliquot TCGA-GC-A3WC-10A-01D-A22Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/634e7f81-d802-4990-b0bd-de84315f012f

The open-access MAF lists 169 somatic variants for this specimen: 129 protein-altering or splice-affecting, 35 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 110, Silent 35, Nonsense Mutation 14, Intron 3, 5'Flank 2, Frame Shift Ins 2, Splice Site 1, Frame Shift Del 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1637A>G p.Q546R | Missense Mutation (SNP) | VAF 29/64 reads (45%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.934); catalogued as rs397517201, COSV55875400, COSV55876869, COSV55877455; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.396G>C p.K132N | Missense Mutation (SNP) | VAF 12/70 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs866775781, COSV52688381, COSV52705927, COSV52891203, COSV53339296; ClinVar: conflicting interpretations of pathogenicity / likely pathogenic; called by muse, mutect2, varscan2
- ABI3BP | c.1484C>T p.P495L | Missense Mutation (SNP) | VAF 94/215 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV52553742; called by muse, mutect2, varscan2
- ACY3 | c.164C>G p.P55R | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54830491; called by muse, mutect2, varscan2
- AFAP1 | c.2003C>T p.S668F | Missense Mutation (SNP) | VAF 35/224 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV100631480, COSV61795722; called by muse, mutect2, varscan2
- ALG1 | c.307T>C p.Y103H | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV52159747; called by muse, mutect2, varscan2
- AMPD3 | c.947C>T p.T316I (on ENST00000396553 / NM_001025389.2; = p.T325I on NM_000480.3) | Missense Mutation (SNP) | VAF 45/218 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV67332915; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.1458G>A p.M486I | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.968); catalogued as COSV51860477; called by muse, mutect2, varscan2
- ANKRD52 | c.991G>A p.E331K | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.338); catalogued as COSV57283933, COSV99921428; called by muse, mutect2, varscan2
- ANO4 | c.196G>A p.E66K (on ENST00000392977 / NM_001286615.2; = p.E31K on NM_178826.4) | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV54596090, COSV54604820; called by muse, mutect2, varscan2
- ARHGAP35 | c.3808G>T p.E1270* | Nonsense Mutation (SNP) | VAF 19/89 reads (21%) | catalogued as COSV68334553; called by muse, mutect2, varscan2
- ARHGAP44 | c.300G>C p.E100D | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.44); PolyPhen benign (0.051); catalogued as COSV52404214; called by muse, varscan2
- ARHGEF4 | c.329C>T p.P110L | Missense Mutation (SNP) | VAF 19/155 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.108); catalogued as COSV58131684; called by muse, mutect2, varscan2
- ARID2 | c.202C>T p.Q68* | Nonsense Mutation (SNP) | VAF 16/82 reads (20%) | catalogued as COSV100537171; called by muse, varscan2
- ARVCF | c.2275C>T p.R759C | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.453); catalogued as rs1173552444, COSV52890133; called by muse, mutect2, varscan2
- ASIC2 | c.403G>A p.E135K | Missense Mutation (SNP) | VAF 27/155 reads (17%) | SIFT tolerated (0.47); PolyPhen benign (0.024); catalogued as COSV63304667, COSV63332408; called by muse, mutect2, varscan2
- ATAD2 | c.607G>C p.E203Q | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.625); catalogued as COSV54879155, COSV54887828; called by muse, mutect2, varscan2
- ATP1B2 | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT tolerated (0.43); PolyPhen benign (0.239); catalogued as COSV51515163; called by muse, mutect2, varscan2
- BAG5 | c.241G>C p.E81Q | Missense Mutation (SNP) | VAF 29/140 reads (21%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.892); catalogued as COSV54572977; called by muse, mutect2, varscan2
- C11orf80 | c.1573G>A p.D525N | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.133); catalogued as rs766454375, COSV58994723; called by muse, mutect2, varscan2
- CABLES1 | c.1448C>A p.T483K (on ENST00000256925 / NM_001100619.2; = p.T218K on NM_138375.2) | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56938146; called by muse, mutect2, varscan2
- CACNA1I | c.695C>A p.A232E | Missense Mutation (SNP) | VAF 22/162 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV60813475; called by muse, mutect2, varscan2
- CCDC183 | c.699C>G p.I233M | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.085); catalogued as COSV61033972, COSV61042013; called by muse, mutect2, varscan2
- CDR1 | c.505C>G p.R169G | Missense Mutation (SNP) | VAF 67/346 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0.349); catalogued as COSV65164216, COSV65164907; called by muse, mutect2, varscan2
- CHSY1 | c.1211C>T p.A404V | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.243); catalogued as COSV54256555; called by muse, mutect2, varscan2
- CNKSR3 | c.1177C>G p.R393G | Missense Mutation (SNP) | VAF 15/170 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.33); catalogued as rs762767264, COSV70481766; called by muse, mutect2
- COX7B2 | c.103C>G p.H35D | Missense Mutation (SNP) | VAF 9/96 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.929); catalogued as COSV57224144; called by muse, mutect2
- CPAMD8 | c.1831G>A p.V611I (on ENST00000651564; = p.V564I on NM_015692.5) | Missense Mutation (SNP) | VAF 17/116 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.075); catalogued as rs374200163; called by muse, mutect2, varscan2
- CREB3L2 | c.857C>T p.P286L | Missense Mutation (SNP) | VAF 36/207 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57801009; called by muse, mutect2, varscan2
- DGKK | c.3490G>A p.D1164N | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.343); catalogued as COSV65706883, COSV65707020; called by muse, mutect2, varscan2
- DNAH8 | c.7735C>T p.R2579* | Nonsense Mutation (SNP) | VAF 21/96 reads (22%) | catalogued as rs763871040, COSV100543222; called by muse, mutect2, varscan2
- DOCK11 | c.5473G>A p.E1825K | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.066); catalogued as COSV52249027, COSV99354548; called by muse, mutect2, varscan2
- DOCK8 | c.1286-2A>T p.X429_splice | Splice Site (SNP) | VAF 13/66 reads (20%) | catalogued as COSV66636373; called by muse, mutect2, varscan2
- DTX1 | c.1426G>A p.G476R | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV55655676; called by muse, mutect2, varscan2
- FAM169A | c.1853C>G p.S618C | Missense Mutation (SNP) | VAF 22/168 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57189152; called by muse, mutect2, varscan2
- FAT1 | c.7349C>G p.S2450* | Nonsense Mutation (SNP) | VAF 25/164 reads (15%) | catalogued as COSV71673814, COSV71675311; called by muse, mutect2, varscan2
- FGD1 | c.1066C>T p.P356S | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV64309829; called by muse, mutect2, varscan2
- FHDC1 | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.58); PolyPhen benign (0.01); catalogued as COSV52603952; called by muse, mutect2, varscan2
- FMOD | c.668G>A p.R223Q | Missense Mutation (SNP) | VAF 74/270 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.081); catalogued as rs199917381, COSV61610470; called by muse, mutect2, varscan2
- GLRA2 | c.104G>C p.G35A | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as COSV54344761, COSV54348480; called by muse, mutect2, varscan2
- GOLGA1 | c.2288G>A p.R763Q | Missense Mutation (SNP) | VAF 25/213 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.537); catalogued as rs146171341; called by muse, mutect2, varscan2
- GOLIM4 | c.898G>A p.E300K | Missense Mutation (SNP) | VAF 62/145 reads (43%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.461); catalogued as COSV58332413; called by muse, mutect2, varscan2
- GON4L | c.2698A>T p.I900F | Missense Mutation (SNP) | VAF 31/126 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.556); catalogued as COSV99676062; called by muse, mutect2, varscan2
- GPLD1 | c.2497C>G p.H833D | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.296); catalogued as rs773206190, COSV51235900; called by muse, mutect2, varscan2
- GPR158 | c.2075C>G p.S692C | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs747271068, COSV66284920; called by muse, mutect2, varscan2
- H1-7 | c.448G>A p.A150T | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.74); PolyPhen benign (0.015); catalogued as rs1398113970, COSV58602808; called by muse, mutect2
- HUNK | c.1979G>A p.R660Q | Missense Mutation (SNP) | VAF 15/121 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as rs749763269, COSV54235387; called by muse, mutect2, varscan2
- IFT172 | c.437C>G p.S146C | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV53134327, COSV53140652; called by muse, mutect2, varscan2
- IL12RB1 | c.1537G>A p.G513S | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV74045690; called by muse, mutect2, varscan2
- IRF2BP1 | c.1225G>A p.G409S | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.77); PolyPhen benign (0.042); catalogued as rs775205610, COSV56195455; called by muse, mutect2, varscan2
- ISYNA1 | c.776C>T p.S259L | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768859602, COSV54212789; called by muse, mutect2, varscan2
- KDM5A | c.1051G>A p.A351T | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as rs1248630203, COSV66996800; called by muse, mutect2, varscan2
- KEAP1 | c.347G>C p.R116P | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV50634336; called by muse, mutect2, varscan2
- KMT2A | c.11105C>G p.S3702* | Nonsense Mutation (SNP) | VAF 7/47 reads (15%) | catalogued as COSV100630151; called by muse, mutect2, varscan2
- KMT2B | c.5325G>A p.W1775* | Nonsense Mutation (SNP) | VAF 11/83 reads (13%) | catalogued as COSV55859162; called by muse, mutect2, varscan2
- KMT2D | c.3229A>T p.K1077* | Nonsense Mutation (SNP) | VAF 5/30 reads (17%) | catalogued as COSV56445369; called by muse, mutect2, varscan2
- KRT9 | c.608C>T p.P203L | Missense Mutation (SNP) | VAF 31/182 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.014); catalogued as COSV55855771; called by muse, mutect2, varscan2
- KRTAP26-1 | c.571A>T p.S191C | Missense Mutation (SNP) | VAF 55/386 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.819); catalogued as COSV100860443, COSV62129469; called by muse, mutect2, varscan2
- LIN54 | c.19G>A p.E7K | Missense Mutation (SNP) | VAF 45/157 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.109); catalogued as COSV61203145, COSV99060007; called by muse, mutect2, varscan2
- LONRF2 | c.1989G>C p.W663C | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV66542750; called by muse, mutect2, varscan2
- MANEA | c.956G>A p.G319E | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779937977, COSV62590048; called by muse, mutect2, varscan2
- MEPCE | c.868C>A p.L290I | Missense Mutation (SNP) | VAF 37/143 reads (26%) | SIFT tolerated (0.35); PolyPhen benign (0.027); catalogued as COSV52770167; called by muse, mutect2, varscan2
- METTL24 | c.1024C>T p.Q342* | Nonsense Mutation (SNP) | VAF 16/108 reads (15%) | catalogued as rs1447982948, COSV100133704; called by muse, mutect2, varscan2
- MFF | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as COSV58826954; called by muse, mutect2, varscan2
- MRTO4 | c.377G>C p.R126P | Missense Mutation (SNP) | VAF 23/150 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.558); catalogued as COSV57673069, COSV57674772; called by muse, mutect2, varscan2
- MTUS1 | c.1838A>C p.E613A | Missense Mutation (SNP) | VAF 36/170 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.536); catalogued as COSV50602157; called by muse, mutect2, varscan2
- MYBPC2 | c.409G>C p.E137Q | Missense Mutation (SNP) | VAF 26/155 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV63100575; called by muse, mutect2, varscan2
- MYO9A | c.5140G>C p.E1714Q | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); catalogued as COSV61859507; called by muse, mutect2, varscan2
- MYT1 | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.162); catalogued as rs753474853, COSV60515363; called by muse, mutect2, varscan2
- NDUFA12 | c.70C>A p.L24I | Missense Mutation (SNP) | VAF 33/211 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.009); catalogued as COSV59846437; called by muse, mutect2, varscan2
- NUMB | c.587G>C p.R196P (on ENST00000355058; = p.R185P on NM_003744.5) | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV61831377, COSV61832574; called by muse, mutect2, varscan2
- NUP188 | c.3502C>T p.R1168W | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.644); catalogued as rs1405414818, COSV65362592; called by muse, mutect2, varscan2
- NUP210L | c.628G>C p.E210Q | Missense Mutation (SNP) | VAF 112/368 reads (30%) | SIFT tolerated (0.55); PolyPhen benign (0.005); catalogued as COSV55159433; called by muse, mutect2, varscan2
- OLFM3 | c.51G>C p.M17I | Missense Mutation (SNP) | VAF 23/118 reads (19%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.001); catalogued as COSV58798690; called by muse, mutect2, varscan2
- OR8D1 | c.716G>A p.G239E | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); catalogued as rs1254736351, COSV63442643; called by muse, mutect2, varscan2
- PAMR1 | c.1819G>A p.V607M (on ENST00000619888 / NM_001001991.3; = p.V624M on NM_015430.4) | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.01); catalogued as rs148541461, COSV53517310; called by muse, mutect2, varscan2
- PCDHA11 | c.2225G>A p.R742H | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs374687707, COSV56514685; called by muse, mutect2, varscan2
- PHEX | c.377G>C p.R126T | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.51); PolyPhen benign (0.018); catalogued as COSV65079624; called by muse, mutect2, varscan2
- PIAS3 | c.1606C>A p.Q536K | Missense Mutation (SNP) | VAF 34/115 reads (30%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.857); catalogued as COSV57908859; called by muse, mutect2, varscan2
- PKHD1 | c.10327A>G p.S3443G | Missense Mutation (SNP) | VAF 26/132 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0.006); catalogued as rs755692013, COSV64402165; called by muse, mutect2, varscan2
- PLCG2 | c.313G>A p.V105I | Missense Mutation (SNP) | VAF 38/167 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as rs754914807, COSV63877650; called by muse, mutect2, varscan2
- PPFIA3 | c.2773G>T p.E925* | Nonsense Mutation (SNP) | VAF 25/169 reads (15%) | catalogued as COSV61953583; called by muse, mutect2, varscan2
- PRF1 | c.883A>G p.T295A | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV64616028; called by muse, mutect2, varscan2
- PTPN14 | c.872T>G p.I291S | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.185); catalogued as COSV65289436; called by muse, mutect2, varscan2
- RAB20 | c.218C>T p.A73V | Missense Mutation (SNP) | VAF 32/115 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780762082, COSV57442231; called by muse, mutect2, varscan2
- RFC4 | c.404G>A p.R135H | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.299); catalogued as rs764526307, COSV56218958; called by muse, mutect2, varscan2
- RFX3 | c.434G>A p.G145D | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT tolerated (0.62); PolyPhen benign (0.09); catalogued as rs1053061916, COSV56526335; called by muse, mutect2, varscan2
- RIPK3 | c.226G>C p.E76Q | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.313); catalogued as COSV53477917; called by muse, mutect2, varscan2
- SCRIB | c.2801T>A p.L934Q | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57594423; called by muse, mutect2, varscan2
- SEL1L3 | c.767C>G p.S256C | Missense Mutation (SNP) | VAF 26/128 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53550760; called by muse, mutect2, varscan2
- SEMA4G | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs779530961, COSV52969480, COSV52972608; called by muse, mutect2, varscan2
- SEMA6C | c.1408G>C p.E470Q | Missense Mutation (SNP) | VAF 71/204 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV59006567, COSV59007051, COSV59007588; called by muse, mutect2, varscan2
- SENP8 | c.402G>C p.E134D | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV61768439; called by muse, mutect2, varscan2
- SETDB1 | c.2018A>G p.Y673C | Missense Mutation (SNP) | VAF 35/119 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.219); catalogued as rs777467787, COSV54993659; called by muse, mutect2, varscan2
- SLIT3 | c.1963C>A p.L655M | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs760808564, COSV60636239; called by muse, mutect2, varscan2
- SPTBN1 | c.3925C>G p.L1309V | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.836); catalogued as COSV61695245; called by muse, mutect2, varscan2
- STK33 | c.461G>T p.S154I | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV59411099; called by mutect2, varscan2
- TACC2 | c.4837G>T p.D1613Y | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.466); catalogued as rs1412699462, COSV57776166; called by muse, mutect2, varscan2
- TAF12 | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.099); catalogued as rs376483218; called by muse, mutect2, varscan2
- TBC1D2 | c.861G>C p.Q287H | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV59789560; called by muse, mutect2, varscan2
- TENM4 | c.5126C>A p.P1709H | Missense Mutation (SNP) | VAF 33/228 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV53678177; called by muse, mutect2, varscan2
- TLR7 | c.2674G>C p.D892H | Missense Mutation (SNP) | VAF 29/226 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66125776; called by muse, mutect2, varscan2
- TMPRSS6 | c.1954G>C p.E652Q | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as COSV60983715; called by muse, mutect2
- TOR4A | c.1080C>G p.I360M | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); catalogued as COSV62626580, COSV62627733; called by muse, mutect2, varscan2
- TRIB3 | c.904G>A p.E302K | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs1028401819, COSV53933030; called by muse, mutect2, varscan2
- TRIM5 | c.962G>A p.S321N | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.119); catalogued as COSV59902112; called by muse, mutect2, varscan2
- TTN | c.233A>G p.Y78C | Missense Mutation (SNP) | VAF 24/151 reads (16%) | PolyPhen probably damaging (0.95); catalogued as COSV60399138; called by muse, mutect2, varscan2
- TXNIP | c.580G>A p.E194K | Missense Mutation (SNP) | VAF 22/181 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.025); catalogued as COSV65220433; called by muse, mutect2, varscan2
- VAPA | c.83C>T p.P28L | Missense Mutation (SNP) | VAF 22/115 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61299586; called by muse, mutect2, varscan2
- VIPR2 | c.94C>T p.Q32* | Nonsense Mutation (SNP) | VAF 26/138 reads (19%) | catalogued as COSV100058499; called by muse, mutect2, varscan2
- WDR70 | c.35C>T p.S12L | Missense Mutation (SNP) | VAF 25/125 reads (20%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV54285719; called by muse, mutect2, varscan2
- YJEFN3 | c.128C>G p.S43C | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV53065489; called by muse, mutect2, varscan2
- ZC2HC1A | c.538C>G p.P180A | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs769083996, COSV55671813; called by muse, mutect2, varscan2
- ZNF660 | c.183G>C p.Q61H | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.731); catalogued as COSV100502717, COSV59550145; called by muse, varscan2
- ZNF660 | c.248G>C p.C83S | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59550156; called by muse, varscan2
- HCFC1R1 | c.110_112del p.G37del | In Frame Del (DEL) | VAF 6/46 reads (13%) | called by pindel, varscan2
- HNRNPUL1 | c.67C>G p.R23G | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.15); called by muse, mutect2
- KIF16B | c.2173C>T p.Q725* | Nonsense Mutation (SNP) | VAF 31/140 reads (22%) | called by muse, mutect2, varscan2
- KLF5 | c.945_948del p.A316Rfs*6 | Frame Shift Del (DEL) | VAF 21/154 reads (14%) | called by mutect2, pindel, varscan2
- KMT2B | c.5462dup p.L1822Tfs*12 | Frame Shift Ins (INS) | VAF 9/66 reads (14%) | called by mutect2, pindel, varscan2
- LRRC43 | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.048); called by muse, mutect2
- MCTP2 | c.511C>T p.H171Y | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2
- NDRG2 | c.827C>G p.S276* (on ENST00000298687 / NM_001354570.1; = p.S262* on NM_016250.3 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 7/41 reads (17%) | called by muse, mutect2, varscan2
- P4HB | c.1291G>C p.E431Q | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SIK2 | c.364A>T p.K122* | Nonsense Mutation (SNP) | VAF 14/74 reads (19%) | called by muse, mutect2, varscan2
- TLN2 | c.1682T>G p.V561G | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- TMOD4 | c.295C>T p.Q99* | Nonsense Mutation (SNP) | VAF 24/136 reads (18%) | called by muse, mutect2, varscan2
- UBR4 | c.5374G>A p.V1792I | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.92); PolyPhen benign (0); called by muse, mutect2
- ZFP36L1 | c.636dup p.T213Hfs*24 | Frame Shift Ins (INS) | VAF 26/161 reads (16%) | called by mutect2, pindel, varscan2
- ADAM17 | c.1743C>T p.F581= | Silent (SNP) | VAF 32/114 reads (28%) | catalogued as rs773721139, COSV60402168; called by muse, mutect2, varscan2
- ARHGAP32 | c.5034G>A p.L1678= (on ENST00000310343 / NM_001378025.1; = p.L1329= on NM_014715.4) | Silent (SNP) | VAF 24/132 reads (18%) | catalogued as COSV59856790; called by muse, mutect2, varscan2
- BEST3 | c.846C>T p.F282= | Silent (SNP) | VAF 30/183 reads (16%) | catalogued as COSV58299783, COSV58306744; called by muse, mutect2, varscan2
- CACNA1A | c.714T>C p.L238= | Silent (SNP) | VAF 14/112 reads (13%) | catalogued as rs1451920573, COSV64214329; ClinVar: likely benign; called by mutect2, varscan2
- CCDC125 | c.471C>T p.A157= | Silent (SNP) | VAF 8/59 reads (14%) | catalogued as COSV67289057; called by muse, mutect2
- CD69 | c.15T>C p.N5= | Silent (SNP) | VAF 15/117 reads (13%) | catalogued as rs149884332, COSV57304016; called by muse, mutect2, varscan2
- CNBD1 | c.523C>T p.L175= | Silent (SNP) | VAF 5/38 reads (13%) | catalogued as COSV101575297, COSV72976810; called by muse, mutect2, varscan2
- CPNE8 | c.1694G>A p.*565= | Silent (SNP) | VAF 6/39 reads (15%) | called by muse, mutect2, varscan2
- DOCK4 | c.964C>T p.L322= | Silent (SNP) | VAF 13/81 reads (16%) | catalogued as COSV70327101; called by muse, mutect2, varscan2
- GIN1 | c.1212G>A p.L404= | Silent (SNP) | VAF 48/235 reads (20%) | catalogued as COSV67536928; called by muse, mutect2, varscan2
- ISOC1 | c.261C>T p.F87= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as COSV51492974; called by muse, mutect2, varscan2
- LGALS9C | c.603G>A p.Q201= | Silent (SNP) | VAF 29/208 reads (14%) | catalogued as COSV60196842; called by muse, mutect2, varscan2
- MAGEA8 | c.306T>C p.A102= | Silent (SNP) | VAF 30/186 reads (16%) | catalogued as COSV54065249; called by muse, mutect2, varscan2
- MAGEB6B | c.858T>A p.G286= | Silent (SNP) | VAF 41/226 reads (18%) | catalogued as COSV101301706, COSV69689987; called by muse, mutect2, varscan2
- MAMDC4 | c.3489C>G p.L1163= (on ENST00000445819; = p.L1084= on NM_206920.3) | Silent (SNP) | VAF 17/51 reads (33%) | catalogued as COSV56377606; called by muse, mutect2, varscan2
- MDC1 | c.2841G>A p.Q947= | Silent (SNP) | VAF 23/130 reads (18%) | catalogued as COSV64524486, COSV64528355; called by muse, mutect2, varscan2
- MKX | c.120C>T p.R40= | Silent (SNP) | VAF 11/49 reads (22%) | catalogued as rs534056794, COSV65393504; called by muse, mutect2, varscan2
- NCOA7 | c.1536C>T p.N512= | Silent (SNP) | VAF 15/80 reads (19%) | catalogued as COSV57661095; called by muse, mutect2, varscan2
- NUP153 | c.798C>T p.Y266= | Silent (SNP) | VAF 18/82 reads (22%) | catalogued as rs750932232, COSV50462078; called by muse, mutect2, varscan2
- P4HB | c.1002G>A p.L334= | Silent (SNP) | VAF 28/166 reads (17%) | catalogued as COSV58943134; called by muse, varscan2
- PICK1 | c.1071C>G p.V357= | Silent (SNP) | VAF 16/76 reads (21%) | catalogued as COSV57637525; called by muse, mutect2, varscan2
- PLCB2 | c.555C>G p.L185= | Silent (SNP) | VAF 15/79 reads (19%) | catalogued as COSV53038866; called by muse, mutect2, varscan2
- PLPPR4 | c.1383C>T p.S461= | Silent (SNP) | VAF 40/136 reads (29%) | catalogued as COSV64567935; called by muse, mutect2, varscan2
- PLVAP | c.483G>A p.L161= | Silent (SNP) | VAF 11/73 reads (15%) | catalogued as COSV53088127; called by muse, mutect2, varscan2
- PMEL | c.1722C>G p.T574= | Silent (SNP) | VAF 15/92 reads (16%) | catalogued as COSV59389104; called by muse, mutect2, varscan2
- PRAMEF15 | c.681C>A p.T227= | Silent (SNP) | VAF 26/311 reads (8%) | called by muse, mutect2, varscan2
- PREX2 | c.912G>C p.V304= | Silent (SNP) | VAF 16/160 reads (10%) | catalogued as COSV55803679; called by muse, mutect2
- PRICKLE2 | c.1506C>T p.F502= (on ENST00000295902; = p.F446= on NM_198859.4) | Silent (SNP) | VAF 32/114 reads (28%) | catalogued as rs752615709, COSV55772783; called by muse, mutect2, varscan2
- SEMA3D | c.1353G>A p.Q451= | Silent (SNP) | VAF 37/212 reads (17%) | catalogued as rs775160821, COSV52406832; called by muse, mutect2, varscan2
- SENP7 | c.2196A>G p.P732= | Silent (SNP) | VAF 29/68 reads (43%) | catalogued as COSV58621341; called by muse, mutect2, varscan2
- STRIP1 | c.349C>T p.L117= | Silent (SNP) | VAF 13/62 reads (21%) | catalogued as COSV63930161; called by muse, mutect2, varscan2
- TRPC5 | c.2904A>G p.Q968= | Silent (SNP) | VAF 5/76 reads (7%) | catalogued as COSV53304594; called by muse, mutect2
- TXNIP | c.267G>C p.V89= | Silent (SNP) | VAF 19/158 reads (12%) | catalogued as rs782294579, COSV65221639; called by muse, mutect2, varscan2
- TXNIP | c.93G>C p.V31= | Silent (SNP) | VAF 7/106 reads (7%) | catalogued as COSV65221630; called by muse, mutect2
- ZFYVE26 | c.6543G>A p.V2181= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as COSV61334357; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73850304 G>C | 5'Flank (SNP) | VAF 5/34 reads (15%) | called by muse, mutect2, varscan2
- CFAP54 | c.8281+30A>G | Intron (SNP) | VAF 5/33 reads (15%) | called by muse, mutect2
- COCH | c.928+309G>C | Intron (SNP) | VAF 21/83 reads (25%) | catalogued as COSV53553427; called by muse, mutect2, varscan2
- NFASC | c.2470+2016C>T | Intron (SNP) | VAF 14/48 reads (29%) | catalogued as COSV58383226; called by muse, mutect2, varscan2
- ZNF22 | chr10:45000851 C>A | 5'Flank (SNP) | VAF 4/12 reads (33%) | catalogued as COSV53584780; called by muse, mutect2, varscan2
